Surgical pathology report (de-identified scan), TCGA case TCGA-B6-A0RS, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Duke, specimen TCGA-B6-A0RS-01A (Primary Tumor).

by

Gross Examination:

Received is a container labeled with the patient's name, history number and date. In addition the container is labeled "left breast". The specimen is received in the fresh state and consists of a breast and attached axillary tail weighing 560 grams and measuring 27.0 x 17.5 x 3.0 cm. in greatest dimension. The overlying skin ellipse measures 13.5 cm. in length with a maximum diameter of 7.0 cm. The skin is notable for a large bruise in the lower outer quadrant extending from the areola to the skin edge measuring 3.0 x 1.5 cm. in greatest dimensions. The skin is otherwise unremarkable. Palpation reveals a 2.5 x 2.0 x 2.5 cm. firm nodule adjacent to the nipple at the intersection of the upper and lower inner quadrants. The pectoralis fascia has been previously inked with Alcian blue and two longitudinal incisions made parallel to the long axis of the specimen each measuring 9.5 cm. in length. The firm area extends to a point 1.2 cm. from the deep surgical margin. Sections will be submitted in the following block order.

Block 1 - firm area to include deep margin

- Block I - firm area to include deep margin.
Block II - additional firm area to include deep margin.
Block III - additional firm area to include deep margin.
Block IV - skin adjacent to firm area.
Block V - mid nipple.
Block VI - representative section from upper outer quadrant.
Block VII - representative section from lower outer quadrant.
Block VIII - representative section from lower inner quadrant.
Block IX - representative section from upper inner quadrant.
Block X - lymph nodes zone I.
Block XI - lymph nodes zone II.
Block XII - lymph nodes zone III.
Block XIII - additional lymph nodes zone III.

al/Syn-chronous Primary		X
as is (circle):		X
viewed in file		

DIAGNOSIS:

"LEFT" BREAST, MASTECTOMY:

- A. INFILTRATING DUCTAL CARCINOMA (2.5 X 2.0 X 2.5 CM.), N.S.A.B.P. NUCLEAR GRADE POORLY DIFFERENTIATED, HISTOLOGIC GRADE 3 OF 3.
- B. NO CARCINOMA IDENTIFIED IN SURGICAL MARGINS.
- C. FIBROCYSTIC CHANGES:
1. FOCAL MODERATE EPITHELIAL HYPERPLASIA.
2. SMALL CYSTS.
3. APOCRINE METAPLASIA.
4. FIBROSIS.

"LEFT" AXILLARY DISSECTION: NO CARCINOMA IDENTIFIED IN 15 LYMPH NODES.

Source: NCI Genomic Data Commons file c0f965cf-170b-4128-8128-043e64c2003b (TCGA-B6-A0RS.6E169005-180B-42C5-9CDC-F6699FAB5AB5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).